Somatic mutation profile of tumor specimen TCGA-77-7465-01A (aliquot TCGA-77-7465-01A-11D-2042-08) from TCGA case TCGA-77-7465, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.0 years (21,548 days).
Specimen TCGA-77-7465-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6bdf63f-dea8-4020-aa98-958938b6f943.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-7465-10A (Blood Derived Normal), aliquot TCGA-77-7465-10A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/880f3797-66d1-4565-8ee8-f9f9f39c7b37

The open-access MAF lists 429 somatic variants for this specimen: 318 protein-altering or splice-affecting, 98 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 265, Silent 98, Nonsense Mutation 29, Frame Shift Del 10, RNA 8, Splice Site 6, Frame Shift Ins 5, Intron 2, Nonstop Mutation 1, Translation Start Site 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 11/18 reads (61%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- FGFR3 | c.*194G>C | 3'UTR (SNP) | VAF 94/168 reads (56%) | catalogued as rs28931614, CM940785, CM940786, CX090489, COSV53399372, COSV99602429; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 30/52 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.2362G>T p.A788S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); catalogued as COSV100252859; called by muse, mutect2, varscan2
- ADAM19 | c.727T>A p.Y243N | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV99977614; called by muse, mutect2, varscan2
- ADCY10 | c.2833C>T p.Q945* | Nonsense Mutation (SNP) | VAF 35/98 reads (36%) | catalogued as COSV100896927; called by muse, mutect2, varscan2
- AHNAK | c.13268G>A p.G4423D | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57232991, COSV99948111; called by muse, mutect2, varscan2
- ANKRD6 | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs746805527, COSV100330102; called by muse, mutect2, varscan2
- ANO2 | c.2000G>C p.G667A (on ENST00000356134 / NM_001278597.3; = p.G671A on NM_001278596.3) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.646); catalogued as COSV100501369; called by muse, mutect2, varscan2
- AQP6 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV100210197; called by muse, mutect2, varscan2
- ARHGAP35 | c.3353C>G p.T1118S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.839); catalogued as COSV101351254; called by muse, mutect2, varscan2
- ATG9A | c.1827G>T p.Q609H | Missense Mutation (SNP) | VAF 87/159 reads (55%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54701286, COSV99521963; called by muse, mutect2, varscan2
- ATP10A | c.850C>A p.H284N | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV100791355, COSV63516967; called by muse, mutect2, varscan2
- ATP13A1 | c.1723C>A p.H575N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99366311; called by muse, mutect2, varscan2
- ATP2A3 | c.670G>T p.V224L | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV99989357; called by muse, mutect2, varscan2
- ATP5MF | c.246C>A p.Y82* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV99461784; called by muse, varscan2
- ATP8B4 | c.2221G>T p.E741* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as COSV99466178; called by muse, mutect2, varscan2
- ATRNL1 | c.3756G>A p.W1252* | Nonsense Mutation (SNP) | VAF 17/31 reads (55%) | catalogued as COSV100371420; called by muse, mutect2, varscan2
- BCL11A | c.1517G>T p.S506I (on ENST00000335712 / NM_001365609.1; = p.S540I on NM_018014.4) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as COSV100185896; called by muse, mutect2, varscan2
- BCL9L | c.1694A>G p.H565R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV99419562; called by muse, mutect2, varscan2
- BRWD1 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV100313404; called by muse, mutect2, varscan2
- BTN1A1 | c.1547T>A p.L516Q | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV99764441; called by muse, mutect2, varscan2
- C17orf64 | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV99293529; called by muse, mutect2, varscan2
- C22orf23 | c.532C>A p.L178M | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99317370; called by muse, mutect2, varscan2
- CACNA1A | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64211533; called by muse, mutect2, varscan2
- CACNA1C | c.6056T>A p.F2019Y (on ENST00000399634 / NM_001167625.1; = p.F1948Y on NM_000719.7) | Missense Mutation (SNP) | VAF 133/237 reads (56%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100219649; called by muse, mutect2, varscan2
- CADM2 | c.1190-2A>T p.X397_splice (on ENST00000407528 / NM_001167674.2; = p.X399_splice on NM_153184.4) | Splice Site (SNP) | VAF 13/29 reads (45%) | catalogued as COSV101057032; called by muse, mutect2, varscan2
- CADPS | c.3733C>A p.R1245S | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as COSV51891605, COSV99339182; called by muse, mutect2, varscan2
- CADPS | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV51873189; called by muse, mutect2, varscan2
- CALHM5 | c.614C>A p.S205Y | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100635620, COSV62068848; called by muse, mutect2, varscan2
- CARMIL1 | c.989G>T p.S330I | Missense Mutation (SNP) | VAF 105/218 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as COSV100278205; called by muse, mutect2, varscan2
- CASP8 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as rs1339962485, COSV51846409, COSV51847390, COSV51855757; called by muse, mutect2, varscan2
- CCBE1 | c.608A>G p.K203R | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as COSV101232846; called by muse, mutect2, varscan2
- CCN4 | c.436T>C p.C146R | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs776406379, COSV99137180; called by muse, mutect2, varscan2
- CDC42BPG | c.1580A>T p.Q527L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV100712108; called by muse, mutect2, varscan2
- CDH11 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1567483357, COSV51760581; called by muse, mutect2, varscan2
- CDH2 | c.2702A>G p.Y901C | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99297352; called by muse, mutect2, varscan2
- CDH8 | c.2310C>A p.D770E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.823); catalogued as COSV100181435, COSV100182477; called by muse, mutect2, varscan2
- CECR2 | c.1223G>A p.G408E (on ENST00000342247 / NM_001290047.2; = p.G225E on NM_001290046.1) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868448604, COSV99378335; called by muse, mutect2, varscan2
- CFAP45 | c.587A>T p.K196M | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100928611; called by muse, mutect2, varscan2
- CFAP91 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as COSV56341898, COSV99847226; called by muse, mutect2, varscan2
- CHST14 | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.292); catalogued as rs369563820; called by muse, mutect2, varscan2
- CIT | c.299G>A p.R100K | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99950064; called by muse, mutect2, varscan2
- CNTNAP5 | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 16/34 reads (47%) | catalogued as COSV101442997, COSV101443734; called by muse, mutect2, varscan2
- CNTRL | c.1576A>G p.I526V | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.05); catalogued as rs774796797, COSV99442834; called by muse, mutect2, varscan2
- COA6 | c.377A>G p.*126Wext*6 | Nonstop Mutation (SNP) | VAF 30/62 reads (48%) | catalogued as COSV100784589; called by muse, mutect2, varscan2
- COL21A1 | c.673G>C p.A225P | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV99779153; called by muse, mutect2, varscan2
- COL22A1 | c.1685C>A p.P562Q | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV57365451; called by muse, mutect2, varscan2
- COL26A1 | c.275T>A p.L92H | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100561845; called by muse, mutect2, varscan2
- CSGALNACT1 | c.1085A>G p.Y362C | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV100175163; called by muse, mutect2, varscan2
- CSMD1 | c.3368C>G p.S1123C (on ENST00000520002; = p.S1122C on NM_033225.6) | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs762233647, COSV100149903; called by muse, mutect2, varscan2
- CSMD3 | c.9523G>T p.D3175Y (on ENST00000297405 / NM_001363185.1; = p.D3006Y on NM_052900.3) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52104292, COSV52320378; called by muse, mutect2, varscan2
- CTSE | c.179G>T p.C60F | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.877); catalogued as COSV100733673; called by muse, mutect2, varscan2
- CTSW | c.126C>A p.F42L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100327419; called by muse, mutect2, varscan2
- DAPK1 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100802156; called by muse, mutect2, varscan2
- DCC | c.3605G>T p.S1202I | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs150938467, COSV71431647; called by muse, mutect2, varscan2
- DDI1 | c.299C>A p.A100E | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.508); catalogued as COSV100159720; called by muse, mutect2, varscan2
- DDR2 | c.1358T>C p.M453T | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs767190591, COSV100906638; called by muse, mutect2, varscan2
- DEFB114 | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.221); catalogued as COSV100435406; called by muse, mutect2, varscan2
- DEFB118 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.974); catalogued as COSV53621703, COSV99489133, COSV99489243; called by muse, mutect2, varscan2
- DGKA | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as rs372433929; called by muse, mutect2, varscan2
- DGKK | c.848C>A p.P283Q | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV101053083; called by muse, mutect2, varscan2
- DKK2 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53401224, COSV99569090; called by muse, mutect2, varscan2
- DLAT | c.608C>A p.P203Q | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV99734803; called by muse, mutect2, varscan2
- DMBT1 | c.3120G>T p.M1040I (on ENST00000338354 / NM_001377530.1; = p.M541I on NM_004406.3) | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV100353305; called by muse, mutect2
- DNAI2 | c.1378del p.V460Cfs*36 | Frame Shift Del (DEL) | VAF 23/91 reads (25%) | catalogued as COSV56758145; called by mutect2, pindel, varscan2
- DNMT3A | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as rs764062059, COSV53042298; called by muse, varscan2
- DOCK4 | c.5169C>A p.C1723* | Nonsense Mutation (SNP) | VAF 33/59 reads (56%) | catalogued as COSV101447892; called by muse, mutect2, varscan2
- DOCK5 | c.4969A>G p.I1657V | Missense Mutation (SNP) | VAF 99/191 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747850494, COSV99377168; called by muse, mutect2, varscan2
- DSCAM | c.2463G>T p.W821C | Missense Mutation (SNP) | VAF 87/125 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV101260597; called by muse, mutect2, varscan2
- DTX3L | c.1008G>C p.E336D | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.236); catalogued as rs1462461536, COSV99950069; called by muse, mutect2, varscan2
- EBF2 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as COSV101282230; called by muse, mutect2, varscan2
- EDARADD | c.356A>C p.Q119P (on ENST00000334232 / NM_145861.4; = p.Q109P on NM_080738.4) | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV100512862; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1954T>G p.C652G (on ENST00000361735 / NM_015935.5; = p.C566G on NM_014955.3) | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.928); catalogued as COSV100675929; called by muse, mutect2, varscan2
- EFCAB7 | c.1513A>T p.I505F | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100937701; called by muse, mutect2, varscan2
- EIF2AK4 | c.4427G>A p.R1476H | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs1371975817, COSV99774895; called by muse, mutect2, varscan2
- EPHA3 | c.1011C>G p.N337K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV60713386, COSV60728079; called by muse, mutect2, varscan2
- ERGIC2 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100791992; called by muse, mutect2, varscan2
- ERN2 | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 61/206 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); catalogued as COSV99891741; called by muse, mutect2, varscan2
- ETS2 | c.266G>C p.G89A | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100711308, COSV62872647; called by muse, mutect2
- EXOC3L2 | c.1625G>C p.S542T | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV52972333, COSV99374564; called by muse, mutect2, varscan2
- F11R | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.657); catalogued as rs748099605, COSV57036840, COSV99231107; called by muse, mutect2, varscan2
- FAM71B | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 81/150 reads (54%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs371678306; called by muse, mutect2, varscan2
- FANCM | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as rs1323969534, COSV99361036; called by muse, mutect2, varscan2
- FBXO15 | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 61/203 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99503457; called by muse, mutect2, varscan2
- FBXO34 | c.1877G>A p.R626H | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs372485384; called by muse, mutect2, varscan2
- FCRL6 | c.518del p.G173Efs*93 | Frame Shift Del (DEL) | VAF 31/108 reads (29%) | catalogued as COSV58941238; called by mutect2, pindel, varscan2
- FHOD1 | c.3085C>G p.P1029A | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV99264241; called by muse, mutect2, varscan2
- FHOD3 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as COSV99941635; called by muse, mutect2, varscan2
- FREM2 | c.8845A>G p.R2949G | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1196214187, COSV54851846; called by muse, mutect2, varscan2
- FSCB | c.552T>G p.H184Q | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs560077187, COSV100469463, COSV61217602; called by muse, mutect2, varscan2
- GABRB3 | c.1282C>A p.L428I | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV100160496; called by muse, mutect2, varscan2
- GALNT18 | c.705G>T p.R235S | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99924936; called by muse, mutect2, varscan2
- GIP | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs779303928, COSV100656951; called by muse, mutect2, varscan2
- GLDN | c.302C>A p.A101E | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs887819209, COSV100117793, COSV59090628; called by muse, mutect2, varscan2
- GOLGA3 | c.2384G>C p.G795A | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.742); catalogued as rs758634916, COSV99209723; called by muse, mutect2, varscan2
- GPAT2 | c.1545C>A p.H515Q | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.899); catalogued as rs374154429, COSV100853307; called by muse, mutect2, varscan2
- GPM6A | c.197G>T p.R66I | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99704412; called by muse, mutect2, varscan2
- GPR15 | c.269T>A p.V90E | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV99423821; called by muse, mutect2, varscan2
- GRAP2 | c.794T>G p.V265G | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as COSV100703035; called by muse, varscan2
- GRIK2 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs767516446, COSV59713611; called by muse, mutect2, varscan2
- GTF3C1 | c.2324C>T p.P775L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs369341224, COSV100649525, COSV100649782; called by muse, mutect2, varscan2
- GUK1 | c.476-1G>T p.X159_splice | Splice Site (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100451622; called by muse, mutect2, varscan2
- HACE1 | c.1267A>C p.T423P | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99493883; called by muse, mutect2, varscan2
- HAPLN4 | c.817G>T p.G273W | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99363867; called by muse, mutect2, varscan2
- HAS2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 57/121 reads (47%) | catalogued as COSV58262158; called by muse, mutect2, varscan2
- HAS2 | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 106/330 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV100391969; called by muse, mutect2, varscan2
- HCN1 | c.2578C>A p.P860T | Missense Mutation (SNP) | VAF 83/232 reads (36%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.009); catalogued as rs1396579079, COSV100300995, COSV57513254; called by muse, mutect2, varscan2
- HNRNPAB | c.248A>T p.K83I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100359458; called by muse, mutect2, varscan2
- HOXC6 | c.572A>T p.N191I | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99679107; called by muse, mutect2, varscan2
- HSD3B2 | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV101027402; called by muse, mutect2, varscan2
- HUS1B | c.791T>A p.L264* | Nonsense Mutation (SNP) | VAF 61/149 reads (41%) | catalogued as COSV100033795; called by muse, mutect2, varscan2
- IGKV1-8 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 100/219 reads (46%) | catalogued as rs759867046; called by muse, mutect2, varscan2
- IGKV2D-24 | c.281C>T p.T94I | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs764525066; called by muse, mutect2, varscan2
- IGLV2-18 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.246); catalogued as rs1212268146; called by muse, mutect2, varscan2
- IGSF11 | c.1169G>T p.G390V (on ENST00000393775 / NM_001015887.3; = p.G389V on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1322251718, COSV100677484; called by muse, mutect2, varscan2
- IGSF11 | c.181G>T p.V61F (on ENST00000393775 / NM_001015887.3; = p.V60F on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as COSV100677486, COSV61176766; called by muse, mutect2, varscan2
- IGSF11 | c.180G>T p.M60I (on ENST00000393775 / NM_001015887.3; = p.M59I on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as COSV100677248; called by muse, mutect2, varscan2
- IKBKE | c.1280G>T p.R427L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV100898293; called by muse, mutect2, varscan2
- IL10RA | c.102T>G p.F34L | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99923150; called by muse, mutect2, varscan2
- IL16 | c.3738C>G p.F1246L (on ENST00000302987 / NM_172217.5; = p.F545L on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100250866, COSV57155069; called by muse, mutect2, varscan2
- IPO13 | c.2288C>T p.P763L | Missense Mutation (SNP) | VAF 131/254 reads (52%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs1386026288, COSV64893616; called by muse, mutect2, varscan2
- IRAG2 | c.4316T>C p.I1439T (on ENST00000636465; = p.I484T on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.839); catalogued as COSV100209488; called by muse, mutect2, varscan2
- ITGAE | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs201123134, COSV54000260; called by muse, mutect2, varscan2
- ITSN1 | c.1273G>T p.E425* | Nonsense Mutation (SNP) | VAF 8/9 reads (89%) | catalogued as COSV101180582; called by muse, varscan2
- KALRN | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99565326; called by muse, mutect2, varscan2
- KALRN | c.719C>G p.A240G | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53751649, COSV99565330; called by muse, mutect2, varscan2
- KCNA4 | c.1039C>A p.H347N | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100069065; called by muse, mutect2, varscan2
- KCNC2 | c.557C>A p.A186E | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs755326940, COSV100129140; called by muse, mutect2, varscan2
- KIAA1755 | c.1868C>A p.P623H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99642251; called by muse, mutect2, varscan2
- KIF1B | c.496T>G p.L166V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99823623; called by muse, mutect2, varscan2
- KIF1B | c.1165G>T p.G389* (on ENST00000377086 / NM_001365952.1; = p.G383* on NM_015074.3) | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as COSV55812988; called by muse, mutect2, varscan2
- KLB | c.902G>C p.G301A | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as COSV99962255; called by muse, mutect2, varscan2
- KLF1 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1225320685, COSV99322440; called by muse, mutect2, varscan2
- KLK5 | c.674T>C p.I225T | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754078347, COSV100307094; called by muse, mutect2, varscan2
- KLRD1 | c.345C>A p.Y115* | Nonsense Mutation (SNP) | VAF 39/210 reads (19%) | catalogued as COSV100282228; called by muse, mutect2, varscan2
- KMT2D | c.2317del p.Q773Sfs*157 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as COSV56443963; called by mutect2, pindel, varscan2
- KNDC1 | c.4291G>T p.E1431* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100465310; called by muse, mutect2, varscan2
- KRTAP5-10 | c.548G>A p.C183Y | Missense Mutation (SNP) | VAF 235/330 reads (71%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs762746749, COSV100924146; called by muse, mutect2, varscan2
- LCNL1 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.664); catalogued as rs372556522; called by muse, mutect2, varscan2
- LEXM | c.796A>C p.S266R | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100827655; called by muse, mutect2, varscan2
- LHFPL4 | c.222G>T p.E74D | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.075); catalogued as COSV99805539; called by muse, mutect2, varscan2
- LILRB5 | c.656-2A>T p.X219_splice | Splice Site (SNP) | VAF 9/19 reads (47%) | catalogued as COSV100300532; called by muse, mutect2, varscan2
- LIN7A | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776623278, COSV99692313; called by muse, mutect2, varscan2
- LONP1 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 59/148 reads (40%) | catalogued as COSV100638649; called by muse, mutect2, varscan2
- LRFN2 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as rs149939756, COSV57834326; called by muse, mutect2, varscan2
- LRIG3 | c.1255G>C p.D419H | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV100292694; called by muse, mutect2
- MAGI2 | c.3398C>A p.P1133H | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100833640; called by muse, mutect2, varscan2
- MAP4K2 | c.2326C>A p.Q776K | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99581191; called by muse, mutect2, varscan2
- MARCHF10 | c.131A>T p.E44V | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV60890211; called by muse, mutect2, varscan2
- MCF2L | c.418G>T p.D140Y (on ENST00000375608; = p.D108Y on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100982718; called by muse, mutect2, varscan2
- METTL4 | c.1327C>G p.R443G | Missense Mutation (SNP) | VAF 242/327 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100170647; called by muse, mutect2, varscan2
- MIDN | c.923A>C p.Q308P | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV99960261; called by muse, mutect2, varscan2
- MIOX | c.408+2T>A p.X136_splice | Splice Site (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99326962; called by muse, mutect2
- MMP21 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100523610; called by muse, mutect2, varscan2
- MOGAT3 | c.968T>A p.F323Y | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99777207; called by muse, mutect2, varscan2
- MORC1 | c.1150G>T p.G384C | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99226650, COSV99227624; called by muse, mutect2, varscan2
- MORC1 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV99226655; called by muse, mutect2, varscan2
- MOXD1 | c.297A>C p.K99N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.21); catalogued as COSV100381693; called by muse, mutect2, varscan2
- MT1H | c.101G>A p.C34Y | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100190038; called by muse, mutect2, varscan2
- MTMR12 | c.1838A>G p.Y613C | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764463573, COSV99373738; called by muse, mutect2, varscan2
- MUC17 | c.1888A>G p.T630A | Missense Mutation (SNP) | VAF 149/427 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100073937; called by muse, mutect2, varscan2
- MUC5B | c.5616C>G p.Y1872* | Nonsense Mutation (SNP) | VAF 25/40 reads (63%) | catalogued as COSV101500474; called by muse, mutect2, varscan2
- MYO7B | c.3901G>T p.V1301F | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as rs1195834389, COSV101268252; called by muse, mutect2, varscan2
- NAV3 | c.3470C>G p.S1157C | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99892528; called by muse, mutect2, varscan2
- NETO1 | c.1520G>T p.R507I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100199004, COSV55009777; called by muse, mutect2, varscan2
- NETO2 | c.901A>G p.T301A | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as COSV100292501; called by muse, mutect2, varscan2
- NFS1 | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100931951; called by muse, mutect2, varscan2
- NID2 | c.171del p.V58Wfs*2 | Frame Shift Del (DEL) | VAF 27/66 reads (41%) | catalogued as COSV99356439; called by mutect2, pindel, varscan2
- NLRP8 | c.95A>T p.Y32F | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.071); catalogued as rs745723781, COSV99405482; called by muse, mutect2, varscan2
- NPHP3 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100447032; called by muse, mutect2, varscan2
- NPM2 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV99235755; called by muse, mutect2, varscan2
- NRIP2 | c.44G>A p.C15Y | Missense Mutation (SNP) | VAF 61/113 reads (54%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.36); catalogued as COSV100512847; called by muse, mutect2, varscan2
- NSG2 | c.383C>A p.S128Y | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV100292858; called by muse, mutect2, varscan2
- NUP214 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100845320; called by muse, mutect2, varscan2
- OGDH | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV56055529, COSV99759132; called by muse, varscan2
- OR10S1 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.523); catalogued as COSV101602488; called by muse, mutect2, varscan2
- OR1C1 | c.238del p.Q80Kfs*3 | Frame Shift Del (DEL) | VAF 22/46 reads (48%) | catalogued as COSV68715586; called by mutect2, pindel, varscan2
- OR2F2 | c.94T>G p.L32V | Missense Mutation (SNP) | VAF 78/146 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV101283826, COSV101283839, COSV68832894; called by muse, mutect2, varscan2
- OR2L13 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs553614392, COSV63560530; called by muse, mutect2, varscan2
- OR2T33 | c.442C>A p.L148I | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.044); catalogued as COSV100531794, COSV100532074; called by muse, mutect2, varscan2
- OR4C15 | c.379T>A p.S127T (on ENST00000314644; = p.S73T on NM_001001920.2) | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.329); catalogued as rs1365786004, COSV58951546, COSV58952166; called by muse, mutect2, varscan2
- OR4S1 | c.519C>A p.D173E | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100180276; called by muse, mutect2, varscan2
- OR51E2 | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.129); catalogued as COSV101211358; called by muse, mutect2, varscan2
- OR52A5 | c.738_739insA p.H247Tfs*58 | Frame Shift Ins (INS) | VAF 13/48 reads (27%) | catalogued as COSV100263492; called by mutect2, pindel, varscan2
- OR5A2 | c.298A>T p.T100S | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as COSV100119779, COSV57391186; called by muse, mutect2, varscan2
- OR5B21 | c.650T>C p.F217S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.279); catalogued as COSV100835160, COSV64482076; called by muse, mutect2, varscan2
- OR5H14 | c.149G>C p.W50S | Missense Mutation (SNP) | VAF 205/573 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.641); catalogued as COSV101454217; called by muse, mutect2, varscan2
- OR5I1 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56886245; called by muse, mutect2, varscan2
- OR5M1 | c.835A>T p.T279S | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV101591564; called by muse, mutect2, varscan2
- OR5M1 | c.577C>A p.R193S | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1402604916, COSV101591566; called by muse, mutect2, varscan2
- OR5M3 | c.478T>A p.W160R | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.327); catalogued as COSV100392559; called by muse, mutect2, varscan2
- OR5M8 | c.335A>G p.Y112C | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV100510703; called by muse, mutect2, varscan2
- OR6C2 | c.628G>C p.V210L | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.024); catalogued as COSV100498725; called by muse, mutect2, varscan2
- OR9G1 | c.251G>T p.C84F | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.697); catalogued as COSV100380460; called by muse, mutect2, varscan2
- OR9G1 | c.752A>T p.Y251F | Missense Mutation (SNP) | VAF 58/402 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.947); catalogued as rs896108580, COSV100380461; called by muse, mutect2, varscan2
- OTOGL | c.4621G>A p.E1541K (on ENST00000547103; = p.E1532K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100087434, COSV100088021; called by muse, mutect2, varscan2
- PABPC4 | c.757G>T p.G253* | Nonsense Mutation (SNP) | VAF 23/53 reads (43%) | catalogued as COSV100790887; called by muse, mutect2, varscan2
- PAGE2 | c.108A>C p.K36N | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs370530168, COSV100892306; called by muse, varscan2
- PAK3 | c.1028A>G p.Y343C (on ENST00000262836 / NM_001324328.2; = p.Y328C on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1242658535, COSV99457672; called by muse, mutect2, varscan2
- PATJ | c.3724C>G p.L1242V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100219786; called by muse, mutect2, varscan2
- PCDH1 | c.3067C>A p.R1023S | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.674); catalogued as COSV99746458; called by muse, mutect2, varscan2
- PCDHB3 | c.388T>G p.S130A | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.071); catalogued as COSV50572744; called by muse, mutect2, varscan2
- PDE3A | c.2857G>C p.G953R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100762335; called by muse, mutect2, varscan2
- PDE7B | c.596C>A p.T199K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.333); catalogued as COSV100367870, COSV57502650; called by muse, mutect2, varscan2
- PDIA2 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.8); PolyPhen benign (0.173); catalogued as COSV99249997; called by muse, mutect2
- PEG3 | c.3410G>T p.S1137I | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.308); catalogued as COSV99688906; called by muse, mutect2, varscan2
- PHF14 | c.2455C>G p.P819A | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV101301823; called by muse, mutect2, varscan2
- PI4KA | c.1359G>T p.Q453H | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.709); catalogued as COSV99746971; called by muse, mutect2, varscan2
- PIGO | c.2308G>T p.G770W | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.39); catalogued as COSV99956782; called by muse, mutect2, varscan2
- PLCE1 | c.299A>G p.K100R | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV99595515; called by muse, mutect2, varscan2
- PLEKHA6 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1224188589, COSV99692272; called by muse, mutect2, varscan2
- PLEKHG1 | c.1868G>A p.G623E | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.024); catalogued as COSV100651717; called by muse, mutect2, varscan2
- POLD1 | c.425A>T p.H142L | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as COSV101486890, COSV70956570; called by muse, mutect2, varscan2
- POTEM | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 87/179 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV101304779, COSV69155516; called by muse, mutect2, varscan2
- PPFIA1 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 26/397 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs370268058; called by muse, mutect2
- PPP2R5B | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as COSV99376233; called by muse, mutect2
- PRR14 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV99788469; called by muse, mutect2, varscan2
- PRSS12 | c.2472C>G p.D824E | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483969292, COSV99628437; called by muse, mutect2, varscan2
- PSENEN | c.61G>C p.G21R | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99495217; called by muse, mutect2, varscan2
- PSMB11 | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101273507; called by muse, mutect2, varscan2
- PTPN4 | c.851T>C p.L284S | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as COSV99750525; called by muse, mutect2, varscan2
- RAPGEF1 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs748330721, COSV100940646; called by muse, mutect2, varscan2
- RBM15B | c.1434G>C p.L478F | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100082208; called by muse, mutect2, varscan2
- RFPL3 | c.95C>T p.A32V (on ENST00000249007 / NM_001098535.1; = p.A3V on NM_006604.2) | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as COSV99967149; called by muse, mutect2, varscan2
- RFX2 | c.1595C>G p.S532C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100353871; called by muse, mutect2, varscan2
- RGS12 | c.3590C>T p.A1197V | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.811); catalogued as COSV100123040; called by muse, mutect2, varscan2
- RIMBP2 | c.1834G>A p.D612N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.136); catalogued as COSV99899800; called by muse, mutect2, varscan2
- RIMS1 | c.3434C>A p.P1145H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99327919; called by muse, mutect2, varscan2
- RIPOR2 | c.167A>G p.H56R | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV99429498; called by muse, mutect2, varscan2
- RNF213 | c.6848G>C p.G2283A | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs373156000, COSV100300926; called by muse, mutect2, varscan2
- RPL37 | c.90G>C p.Q30H | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV99947655; called by muse, mutect2
- RSPO2 | c.544A>G p.K182E | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.987); catalogued as COSV99409828; called by muse, mutect2, varscan2
- RTN4R | c.134A>T p.Q45L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99245110; called by muse, mutect2, varscan2
- RUNX1T1 | c.1679A>G p.Q560R (on ENST00000265814 / NM_001198628.1; = p.Q533R on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.034); catalogued as COSV99752884; called by muse, mutect2
- SCN4A | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1227159244, COSV71125975; called by muse, mutect2, varscan2
- SCN9A | c.1209G>A p.M403I | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV100313313; called by muse, mutect2, varscan2
- SDK1 | c.6223A>G p.S2075G | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV101269535; called by muse, mutect2, varscan2
- SEC62 | c.323A>C p.K108T | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.46); catalogued as COSV100428008; called by muse, mutect2
- SEMA6A | c.940A>G p.T314A | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs750274663, COSV99963422; called by muse, mutect2, varscan2
- SERAC1 | c.497A>G p.Y166C | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs759233428, COSV100894857; called by muse, mutect2, varscan2
- SETD1A | c.119A>T p.Y40F | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs953690782, COSV52685687, COSV99353250; called by muse, mutect2, varscan2
- SETD6 | c.653C>A p.A218D (on ENST00000219315 / NM_001160305.4; = p.A194D on NM_024860.3) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99262272; called by muse, mutect2, varscan2
- SHOX2 | c.610A>G p.K204E (on ENST00000441443 / NM_006884.3; = p.K228E on NM_003030.4) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV101273807; called by muse, mutect2, varscan2
- SIGLEC10 | c.1519C>G p.L507V | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1439738732, COSV100219167; called by muse, mutect2, varscan2
- SIGLEC9 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as rs777687821, COSV99142715; called by muse, mutect2, varscan2
- SIGLECL1 | c.500A>T p.E167V | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV100323955; called by muse, mutect2, varscan2
- SLA2 | c.718G>C p.G240R | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99481448; called by muse, mutect2, varscan2
- SLC12A4 | c.1997G>C p.R666P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50455286, COSV99863125; called by muse, mutect2, varscan2
- SLC24A5 | c.984G>C p.K328N | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.069); catalogued as COSV99981785; called by muse, mutect2, varscan2
- SLC27A3 | c.989G>T p.R330L (on ENST00000271857; = p.R202L on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99670007; called by muse, mutect2, varscan2
- SLC34A3 | c.659G>C p.S220T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV100746679; called by muse, varscan2
- SLC5A8 | c.1115A>T p.Y372F | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV101610566; called by muse, mutect2, varscan2
- SLC8A3 | c.848A>G p.K283R | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.993); catalogued as COSV100776268; called by muse, mutect2, varscan2
- SLC9C2 | c.1026T>A p.F342L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV100876829; called by muse, mutect2, varscan2
- SMARCD1 | c.191T>A p.L64* | Nonsense Mutation (SNP) | VAF 35/119 reads (29%) | catalogued as COSV99948127; called by muse, mutect2, varscan2
- SPATA17 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145142638; called by muse, mutect2, varscan2
- SPATA31E1 | c.2194G>T p.E732* | Nonsense Mutation (SNP) | VAF 31/68 reads (46%) | catalogued as COSV100350624, COSV57789681; called by muse, mutect2, varscan2
- STAMBPL1 | c.1273G>T p.V425L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100904967; called by muse, mutect2, varscan2
- STMN4 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99740949; called by muse, mutect2, varscan2
- SUGP2 | c.3232A>T p.K1078* | Nonsense Mutation (SNP) | VAF 73/200 reads (37%) | catalogued as COSV100432024; called by muse, mutect2, varscan2
- SYNE1 | c.3147G>T p.M1049I (on ENST00000367255 / NM_182961.4; = p.M1056I on NM_033071.3) | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99569146; called by muse, mutect2, varscan2
- SYNE1 | c.2360C>A p.A787E (on ENST00000367255 / NM_182961.4; = p.A794E on NM_033071.3) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs147406318, COSV54951838; called by muse, mutect2, varscan2
- SYNE1 | c.2180C>T p.A727V (on ENST00000367255 / NM_182961.4; = p.A734V on NM_033071.3) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV99569155; called by muse, mutect2, varscan2
- TAF1C | c.1744G>T p.G582C | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.719); catalogued as COSV100499676; called by muse, mutect2, varscan2
- TBC1D19 | c.339C>A p.C113* | Nonsense Mutation (SNP) | VAF 20/34 reads (59%) | catalogued as COSV99336527; called by muse, mutect2, varscan2
- TESMIN | c.1265G>C p.G422A | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.787); catalogued as rs999029285, COSV99663775; called by muse, mutect2, varscan2
- THOC2 | c.1726C>G p.P576A | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99833631; called by muse, mutect2, varscan2
- TKTL2 | c.114G>T p.Q38H | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780952965, COSV99761510; called by muse, mutect2, varscan2
- TLR5 | c.1217C>A p.P406H | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV100643314; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4057G>A p.V1353M | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV100836109; called by muse, mutect2, varscan2
- TNR | c.581G>A p.W194* | Nonsense Mutation (SNP) | VAF 47/131 reads (36%) | catalogued as COSV54903163; called by muse, mutect2, varscan2
- TNXB | c.3743C>T p.P1248L (on ENST00000647633; = p.P1001L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.576); catalogued as rs768607753, COSV64476319; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM58 | c.748-2A>G p.X250_splice | Splice Site (SNP) | VAF 15/71 reads (21%) | catalogued as rs1344293457, COSV100825165, COSV63569157; called by muse, mutect2, varscan2
- TRPS1 | c.1374G>T p.Q458H (on ENST00000220888 / NM_001330599.2; = p.Q471H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99631954; called by muse, mutect2, varscan2
- TSPYL6 | c.1101G>C p.Q367H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1453563318, COSV57816071; called by muse, mutect2, varscan2
- TTC17 | c.1600C>T p.H534Y | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV99235506; called by muse, mutect2, varscan2
- TTN | c.11831T>A p.L3944H (on ENST00000591111; = p.L3898H on NM_003319.4) | Missense Mutation (SNP) | VAF 17/31 reads (55%) | catalogued as COSV100618610; called by muse, mutect2, varscan2
- UCHL3 | c.643C>A p.R215S | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101111552, COSV66459385; called by muse, mutect2, varscan2
- UFSP2 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs1561116582, COSV99249166; called by muse, mutect2, varscan2
- UROC1 | c.616A>T p.T206S | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99331686; called by muse, mutect2, varscan2
- USH2A | c.8866G>A p.E2956K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV100237513; called by muse, mutect2, varscan2
- USH2A | c.8396G>T p.G2799V | Missense Mutation (SNP) | VAF 70/123 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100237517; called by muse, mutect2, varscan2
- USP13 | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV99831331; called by muse, mutect2, varscan2
- VAV1 | c.1571A>T p.E524V | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV100409201; called by muse, mutect2, varscan2
- VNN2 | c.531C>A p.Y177* | Nonsense Mutation (SNP) | VAF 27/75 reads (36%) | catalogued as COSV100426847; called by muse, mutect2, varscan2
- WDR72 | c.1490T>A p.F497Y | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100854681; called by muse, mutect2, varscan2
- WFDC3 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs1362661606, COSV99714616; called by muse, mutect2, varscan2
- WNT3A | c.258G>T p.W86C | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52731952, COSV99469708; called by muse, mutect2, varscan2
- ZBTB12 | c.1336G>A p.V446M | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.436); catalogued as rs1175923440, COSV100976991; called by muse, mutect2, varscan2
- ZBTB43 | c.447T>G p.N149K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV100991412; called by muse, mutect2, varscan2
- ZIC1 | c.861C>A p.Y287* | Nonsense Mutation (SNP) | VAF 41/148 reads (28%) | catalogued as COSV51553105, COSV51557963; called by muse, mutect2, varscan2
- ZIC1 | c.1159T>A p.S387T | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99292082; called by muse, mutect2, varscan2
- ZIM2 | c.1389G>T p.E463D | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV99689408; called by muse, mutect2, varscan2
- ZMAT4 | c.193-2A>T p.X65_splice | Splice Site (SNP) | VAF 10/23 reads (43%) | catalogued as COSV52717112; called by muse, mutect2, varscan2
- ZNF165 | c.235A>T p.K79* | Nonsense Mutation (SNP) | VAF 43/88 reads (49%) | catalogued as COSV101055966; called by muse, mutect2, varscan2
- ZNF208 | c.470G>T p.C157F | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV101237154, COSV68101374; called by muse, mutect2, varscan2
- ZNF267 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100339833; called by muse, mutect2, varscan2
- ZNF302 | c.853T>C p.C285R (on ENST00000627982; = p.C206R on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370016318, COSV71063345; called by muse, mutect2, varscan2
- ZNF354C | c.1395G>T p.E465D | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100203592, COSV100203634; called by muse, mutect2, varscan2
- ZNF471 | c.866C>A p.P289Q | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100340697; called by muse, mutect2, varscan2
- ZNF528 | c.1337T>A p.F446Y | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV100846684; called by muse, mutect2, varscan2
- ZNF560 | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100038738; called by muse, mutect2, varscan2
- ZNF670 | c.1007C>G p.P336R | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV100829288; called by muse, mutect2, varscan2
- ZNF835 | c.1494C>G p.D498E | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.012); catalogued as COSV101606366; called by muse, mutect2, varscan2
- ZNF99 | c.2267C>A p.T756N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as COSV101233870; called by muse, mutect2, varscan2
- ARPC3 | c.69_79del p.R25Qfs*16 | Frame Shift Del (DEL) | VAF 21/82 reads (26%) | called by mutect2, pindel, varscan2
- ATXN2L | c.917del p.S306Tfs*111 | Frame Shift Del (DEL) | VAF 30/86 reads (35%) | called by pindel, varscan2
- CHRM3 | c.519del p.L174Sfs*14 | Frame Shift Del (DEL) | VAF 37/183 reads (20%) | called by mutect2, pindel, varscan2
- CSMD3 | c.10607dup p.N3536Kfs*11 (on ENST00000297405 / NM_001363185.1; = p.N3367Kfs*11 on NM_052900.3) | Frame Shift Ins (INS) | VAF 16/104 reads (15%) | called by mutect2, pindel, varscan2
- DYNLL2 | c.142_153del p.K48_N51del | In Frame Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- GPR179 | c.1823C>G p.T608S (on ENST00000621958; = p.T607S on NM_001004334.4) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HOXD13 | c.828dup p.R277Efs*13 | Frame Shift Ins (INS) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- IGHV1-45 | c.309C>A p.S103R | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- IGKV1-37 | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by mutect2, varscan2
- MPHOSPH8 | c.2247del p.P750Qfs*58 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | called by mutect2, pindel, varscan2
- PDE6B | c.2018dup p.K674Qfs*12 | Frame Shift Ins (INS) | VAF 9/22 reads (41%) | called by mutect2, pindel
- RECQL4 | c.1112_1118dup p.L374Qfs*51 | Frame Shift Ins (INS) | VAF 8/50 reads (16%) | called by mutect2, varscan2
- RYR1 | c.12521_12524del p.R4174Pfs*35 | Frame Shift Del (DEL) | VAF 34/111 reads (31%) | called by mutect2, pindel, varscan2
- ACP6 | c.1053A>G p.K351= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as COSV100984232; called by muse, mutect2, varscan2
- AGMO | c.117T>C p.Y39= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV100694323; called by muse, mutect2, varscan2
- ALDH1A3 | c.357G>T p.T119= | Silent (SNP) | VAF 35/118 reads (30%) | catalogued as rs1260832164, COSV100320493; called by muse, mutect2, varscan2
- ALDH3B2 | c.1011C>T p.T337= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100824071; called by muse, mutect2, varscan2
- ANKRD50 | c.693T>A p.L231= | Silent (SNP) | VAF 62/126 reads (49%) | catalogued as COSV101538990; called by muse, mutect2, varscan2
- APOB | c.4842G>A p.L1614= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV99266294; called by muse, mutect2, varscan2
- ARSA | c.252G>T p.P84= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1469297825, COSV99332420; called by muse, mutect2, varscan2
- ASIC2 | c.261A>T p.P87= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV100726632; called by muse, mutect2, varscan2
- ASIC5 | c.435T>A p.T145= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV101539763; called by muse, mutect2, varscan2
- ASXL2 | c.3676T>C p.L1226= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV99711478; called by muse, mutect2, varscan2
- ATP7B | c.369C>A p.A123= | Silent (SNP) | VAF 38/63 reads (60%) | catalogued as COSV99666607; called by muse, mutect2, varscan2
- BEGAIN | c.525C>G p.A175= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100766973; called by muse, mutect2, varscan2
- CCR6 | c.468C>A p.L156= | Silent (SNP) | VAF 35/81 reads (43%) | catalogued as COSV100551118; called by muse, mutect2, varscan2
- CDH18 | c.288T>G p.G96= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as COSV99936014; called by muse, mutect2, varscan2
- CELSR1 | c.6030C>T p.S2010= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV99418794; called by muse, mutect2, varscan2
- CES3 | c.1593A>T p.P531= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV100309969; called by muse, mutect2, varscan2
- CFAP299 | c.438T>A p.T146= | Silent (SNP) | VAF 42/69 reads (61%) | catalogued as COSV100811885; called by muse, mutect2, varscan2
- CIITA | c.729C>A p.I243= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV100162222, COSV60855248; called by muse, mutect2, varscan2
- CKAP2L | c.2112G>T p.L704= | Silent (SNP) | VAF 67/206 reads (33%) | catalogued as COSV100198641; called by muse, mutect2, varscan2
- CLCA2 | c.945G>C p.V315= | Silent (SNP) | VAF 50/82 reads (61%) | catalogued as COSV100991586; called by muse, mutect2, varscan2
- CPN2 | c.756C>T p.A252= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as COSV100103137; called by muse, mutect2, varscan2
- CRYBA1 | c.390G>A p.E130= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99837031; called by muse, mutect2, varscan2
- CTDSPL | c.633T>A p.L211= (on ENST00000273179 / NM_001008392.2; = p.L200= on NM_005808.3) | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as COSV99828814; called by muse, mutect2, varscan2
- DHX34 | c.1089G>T p.L363= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV100169686; called by muse, mutect2, varscan2
- F2RL1 | c.672G>T p.T224= | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as COSV56995043, COSV56996246; called by muse, mutect2, varscan2
- FAT3 | c.10068G>A p.V3356= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV99967376; called by muse, mutect2, varscan2
- FLRT3 | c.1614C>T p.A538= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as COSV99435896; called by muse, mutect2, varscan2
- FLT3 | c.408C>T p.T136= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as COSV99609203; called by muse, mutect2, varscan2
- FOXD4L4 | c.165C>G p.L55= | Silent (SNP) | VAF 50/516 reads (10%) | called by muse, mutect2
- GCN1 | c.5046G>T p.G1682= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV100325500; called by muse, mutect2, varscan2
- GPR4 | c.384G>T p.L128= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV100547107; called by muse, mutect2, varscan2
- GRIN2A | c.4173G>A p.L1391= | Silent (SNP) | VAF 37/119 reads (31%) | catalogued as COSV100410259; called by muse, mutect2, varscan2
- GYPE | c.162G>C p.A54= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV100679340, COSV62263179, COSV62263617; called by muse, mutect2, varscan2
- HCN3 | c.453G>A p.V151= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV100855709; called by muse, mutect2, varscan2
- HECTD4 | c.5400G>T p.A1800= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV101107855; called by muse, varscan2
- HELZ2 | c.2085C>T p.D695= (on ENST00000467148 / NM_001037335.2; = p.D126= on NM_033405.3) | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs540033381, COSV100915627; called by muse, mutect2, varscan2
- HOXC13 | c.552G>A p.A184= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV54499008; called by muse, mutect2, varscan2
- IGSF10 | c.6102A>G p.R2034= | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as COSV99183025; called by muse, mutect2, varscan2
- IRX2 | c.267G>A p.A89= | Silent (SNP) | VAF 28/127 reads (22%) | catalogued as COSV57409959; called by muse, mutect2, varscan2
- ISL1 | c.225C>T p.Y75= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs1260019482, COSV100045518; called by muse, mutect2, varscan2
- KCNH6 | c.555G>T p.T185= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV100121129, COSV59003829; called by muse, mutect2, varscan2
- KCNT1 | c.2559T>C p.C853= (on ENST00000488444; = p.C872= on NM_020822.3) | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV99706031; called by muse, mutect2, varscan2
- KLK4 | c.621T>A p.S207= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as CD157168, COSV100133653; called by muse, mutect2, varscan2
- KRT6B | c.564C>T p.N188= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV52886163, COSV99360820; called by muse, mutect2, varscan2
- KRTCAP3 | c.78C>T p.I26= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99275110; called by muse, mutect2
- LILRA5 | c.810C>A p.G270= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV100006983; called by muse, mutect2, varscan2
- MAGEB6B | c.843G>T p.A281= | Silent (SNP) | VAF 54/88 reads (61%) | catalogued as COSV69689749; called by muse, mutect2, varscan2
- MAGEL2 | c.2190C>A p.G730= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100046018; called by muse, varscan2
- MAGEL2 | c.2124G>T p.L708= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100045887; called by muse, varscan2
- MEFV | c.447C>A p.A149= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99560353, COSV99561023; called by muse, mutect2, varscan2
- MYEOV | c.753C>A p.G251= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV100456676; called by muse, mutect2, varscan2
- MYOCD | c.102T>A p.A34= | Silent (SNP) | VAF 16/22 reads (73%) | catalogued as COSV100590949; called by muse, mutect2, varscan2
- NCAN | c.1359C>A p.P453= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs1179824401, COSV53049037, COSV53062017; called by muse, mutect2, varscan2
- NDRG2 | c.387T>C p.P129= (on ENST00000298687 / NM_001354570.1; = p.P115= on NM_016250.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV100069055; called by muse, mutect2, varscan2
- NIBAN2 | c.1743G>T p.L581= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100031624; called by muse, mutect2, varscan2
- NKX6-2 | c.564C>T p.T188= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs759546562; called by muse, mutect2
- NPAP1 | c.48C>T p.P16= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100275600, COSV61505852; called by muse, mutect2, varscan2
- NPHS1 | c.243G>T p.P81= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100799987; called by muse, mutect2, varscan2
- OR10H1 | c.597C>A p.G199= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV100612432; called by muse, mutect2, varscan2
- OR2H2 | c.297C>A p.I99= | Silent (SNP) | VAF 41/110 reads (37%) | catalogued as COSV100589809; called by muse, mutect2, varscan2
- OR2L13 | c.792C>A p.L264= | Silent (SNP) | VAF 56/111 reads (50%) | catalogued as COSV100813812, COSV99050194; called by muse, mutect2, varscan2
- OR5I1 | c.285C>T p.S95= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100041505; called by muse, mutect2, varscan2
- OR5L2 | c.864G>T p.L288= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV65723398; called by muse, mutect2, varscan2
- OR9G1 | c.75C>T p.G25= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs780805108, COSV100380459; called by muse, varscan2
- OSBP2 | c.1050G>T p.L350= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100213332; called by muse, mutect2, varscan2
- PHF1 | c.969G>A p.K323= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as COSV100992645; called by muse, mutect2, varscan2
- PHF19 | c.1095C>G p.S365= | Silent (SNP) | VAF 68/186 reads (37%) | catalogued as COSV100876385; called by muse, mutect2, varscan2
- PPARD | c.147C>G p.S49= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100283195, COSV100283414; called by muse, mutect2, varscan2
- PRPS2 | c.621G>A p.L207= | Silent (SNP) | VAF 134/181 reads (74%) | catalogued as COSV101037629; called by muse, mutect2, varscan2
- PSMC3 | c.213C>T p.D71= | Silent (SNP) | VAF 43/79 reads (54%) | catalogued as COSV100099625; called by muse, mutect2, varscan2
- RAI1 | c.4797G>T p.V1599= | Silent (SNP) | VAF 70/119 reads (59%) | catalogued as COSV55398047, COSV99884349; called by muse, mutect2, varscan2
- RGS9 | c.1923G>C p.T641= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV99287594; called by muse, mutect2, varscan2
- RIPOR2 | c.480G>A p.K160= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV99428567; called by muse, mutect2, varscan2
- SATB2 | c.594C>A p.S198= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV99611598; called by muse, mutect2, varscan2
- SENP2 | c.1086G>C p.T362= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV99957886; called by muse, mutect2, varscan2
- SIGLEC7 | c.1164G>A p.A388= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs766073645, COSV99978792; called by muse, mutect2, varscan2
- SLC9C2 | c.2859G>T p.L953= | Silent (SNP) | VAF 43/123 reads (35%) | catalogued as rs759397494, COSV62944397; called by muse, mutect2, varscan2
- SLFN11 | c.672A>G p.Q224= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as COSV100390748; called by muse, mutect2, varscan2
- SLX4 | c.2631T>C p.A877= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV99568221; called by muse, mutect2, varscan2
- SNX1 | c.984T>C p.A328= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV99976259; called by muse, mutect2, varscan2
- SOGA3 | c.2244C>A p.P748= | Silent (SNP) | VAF 49/152 reads (32%) | catalogued as COSV100846969; called by muse, mutect2, varscan2
- SOX11 | c.579C>A p.G193= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs561060111, COSV100431249; called by muse, mutect2, varscan2
- TAF2 | c.3150T>A p.T1050= | Silent (SNP) | VAF 92/218 reads (42%) | catalogued as COSV100978747; called by muse, mutect2, varscan2
- TCF4 | c.837G>C p.P279= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100610428, COSV61902720; called by muse, mutect2, varscan2
- TECPR1 | c.1404G>A p.R468= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs767744379, COSV101130583; called by muse, mutect2, varscan2
- TGIF2LX | c.189G>A p.K63= | Silent (SNP) | VAF 37/59 reads (63%) | catalogued as COSV99383433; called by muse, mutect2, varscan2
- TM9SF4 | c.1821C>A p.G607= | Silent (SNP) | VAF 10/169 reads (6%) | catalogued as COSV99454791; called by muse, mutect2
- UBR4 | c.7017G>A p.E2339= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV64394747; called by muse, mutect2, varscan2
- UBTF | c.2184C>T p.D728= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as rs768101144, COSV100255993; called by muse, mutect2, varscan2
- UNC13C | c.3108G>C p.P1036= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV99519409; called by muse, mutect2, varscan2
- UNG | c.204C>A p.A68= (on ENST00000242576 / NM_080911.3; = p.A59= on NM_003362.4) | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as COSV99655395; called by muse, mutect2, varscan2
- USHBP1 | c.261G>T p.V87= | Silent (SNP) | VAF 40/159 reads (25%) | catalogued as COSV99394345; called by muse, mutect2, varscan2
- WWC1 | c.2082G>A p.Q694= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV99515278; called by muse, mutect2, varscan2
- WWOX | c.1113G>C p.L371= | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as COSV101283133; called by muse, mutect2, varscan2
- ZIK1 | c.237T>A p.S79= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100277544; called by muse, mutect2, varscan2
- ZNF257 | c.1593C>T p.T531= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs1318178360, COSV71308243; called by mutect2, varscan2
- ZNF497 | c.519G>A p.A173= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV99568405; called by muse, varscan2
- ZNF521 | c.3402G>A p.G1134= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs1568018808, COSV100832577; called by muse, mutect2, varscan2
- EGFL7 | c.571+305C>T | Intron (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100451998; called by muse, mutect2, varscan2
- EPDR1 | c.-101G>A | 5'UTR (SNP) | VAF 34/85 reads (40%) | catalogued as COSV99554523; called by muse, mutect2, varscan2
- HERC2P3 | n.1487G>C | RNA (SNP) | VAF 31/51 reads (61%) | called by muse, mutect2, varscan2
- LINC02843 | n.438G>T | RNA (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- MIR1251 | n.70C>A | RNA (SNP) | VAF 32/95 reads (34%) | called by muse, mutect2, varscan2
- MIR505 | n.70C>A | RNA (SNP) | VAF 43/56 reads (77%) | catalogued as COSV100990502; called by muse, mutect2, varscan2
- MIR519C | n.70G>T | RNA (SNP) | VAF 35/113 reads (31%) | called by muse, mutect2, varscan2
- MIR519E | n.25G>T | RNA (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- SMTNL1 | c.538+20C>A | Intron (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2
- SNORD115-29 | n.39G>T | RNA (SNP) | VAF 89/347 reads (26%) | catalogued as rs1007843542; called by muse, mutect2, varscan2
- TCP10L3 | n.407G>C | RNA (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100833139; called by mutect2, varscan2
- WNK2 | chr9:93320378 G>T | 3'Flank (SNP) | VAF 28/59 reads (47%) | catalogued as COSV99943165; called by muse, mutect2, varscan2
